Somatic mutation profile of tumor specimen ALCH-B2UU-TTP1-A (aliquot ALCH-B2UU-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2UU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.2 years (21,987 days).
Specimen ALCH-B2UU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 716f99eb-9510-48b3-8f6e-9d724e80fc55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2UU-NB1-A (Blood Derived Normal), aliquot ALCH-B2UU-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bda24c79-06bf-487c-a7ee-04519314a7cc

The open-access MAF lists 74 somatic variants for this specimen: 54 protein-altering or splice-affecting, 11 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 11, Nonsense Mutation 4, 5'UTR 4, Frame Shift Del 2, 3'UTR 2, Intron 2, Frame Shift Ins 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/400 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAMTS20 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1434150093, COSV67125673, COSV67136081, COSV67136513; called by muse, mutect2, varscan2
- ARHGEF26 | c.1002G>C p.K334N | Missense Mutation (SNP) | VAF 147/746 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); catalogued as rs899808579; called by muse, mutect2, varscan2
- C16orf78 | c.478A>G p.M160V | Missense Mutation (SNP) | VAF 47/401 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs367884329; called by muse, mutect2, varscan2
- CCDC17 | c.68C>G p.S23* | Nonsense Mutation (SNP) | VAF 14/107 reads (13%) | catalogued as COSV51972519; called by muse, mutect2, varscan2
- DNAH11 | c.2127C>A p.F709L | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs746839370, COSV60951986, COSV60981348; called by muse, mutect2, varscan2
- DNAH11 | c.4663G>A p.D1555N | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs747220928; called by muse, mutect2, varscan2
- FREM1 | c.6073G>C p.E2025Q | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as COSV66529028; called by muse, mutect2, varscan2
- GRIN2A | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 86/423 reads (20%) | catalogued as rs368026708, COSV58030003; called by muse, mutect2, varscan2
- HNF4A | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 72/433 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as CM082882; called by muse, mutect2, varscan2
- MC2R | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 178/753 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.912); catalogued as rs139177060, COSV59617286; called by muse, mutect2, varscan2
- PPP1R3A | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 86/622 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as rs1057524893; ClinVar: likely benign; called by muse, mutect2, varscan2
- SETD2 | c.6489del p.F2164Lfs*84 | Frame Shift Del (DEL) | VAF 50/249 reads (20%) | catalogued as COSV57439317; called by mutect2, pindel, varscan2
- TNXB | c.4288G>A p.E1430K (on ENST00000647633; = p.E1183K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.784); catalogued as rs781061300, COSV100926391; called by muse, mutect2
- TP53 | c.548C>A p.S183* | Nonsense Mutation (SNP) | VAF 102/485 reads (21%) | catalogued as COSV52662121, COSV52858115, COSV53050787, COSV53082360; called by muse, mutect2, varscan2
- TRIM25 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs1285767624; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); catalogued as rs746552990, COSV66024057; called by muse, mutect2, varscan2
- ZMYM1 | c.779G>C p.S260T | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.492); catalogued as COSV63252981; called by muse, mutect2, varscan2
- ADCY3 | c.2139C>G p.I713M | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ARSL | c.1330A>G p.T444A | Missense Mutation (SNP) | VAF 143/732 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BPNT2 | c.969C>G p.I323M | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C2CD3 | c.6208G>A p.E2070K | Missense Mutation (SNP) | VAF 19/481 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- CASK | c.1485G>C p.K495N | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CASR | c.921G>T p.M307I | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC178 | c.1990T>C p.F664L (on ENST00000383096 / NM_001105528.3; = p.F626L on NM_198995.3) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CFAP20 | c.458G>C p.R153T | Missense Mutation (SNP) | VAF 34/594 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2
- CFAP70 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- CHRD | c.2815G>T p.A939S | Missense Mutation (SNP) | VAF 55/310 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH1 | c.1347G>A p.M449I | Missense Mutation (SNP) | VAF 57/275 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- DNAH12 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 63/284 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DRC1 | c.585del p.K195Nfs*17 | Frame Shift Del (DEL) | VAF 34/203 reads (17%) | called by mutect2, pindel, varscan2
- GALK2 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ILDR1 | c.1045C>G p.L349V (on ENST00000344209 / NM_001199799.2; = p.L305V on NM_175924.4) | Missense Mutation (SNP) | VAF 51/354 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ITGB8 | c.1384C>T p.H462Y | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- MCAM | c.807A>C p.E269D | Missense Mutation (SNP) | VAF 105/575 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- MEGF8 | c.4664G>A p.G1555E (on ENST00000251268 / NM_001271938.2; = p.G1488E on NM_001410.3) | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.936); called by muse, mutect2
- METAP1D | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- MYH11 | c.5578G>C p.D1860H | Missense Mutation (SNP) | VAF 81/539 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NEK1 | c.2606C>A p.P869H | Missense Mutation (SNP) | VAF 43/271 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NFATC3 | c.1784C>A p.S595Y | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PASK | c.2320G>C p.A774P | Missense Mutation (SNP) | VAF 147/713 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDK2 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PRKCE | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 55/360 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RAPGEF3 | c.1537G>C p.E513Q (on ENST00000389212; = p.E471Q on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/384 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- RNF20 | c.1318C>T p.Q440* | Nonsense Mutation (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- ROBO3 | c.3508A>G p.M1170V | Missense Mutation (SNP) | VAF 81/344 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- SALL1 | c.3858G>C p.Q1286H | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA5B | c.1137-1G>C p.X379_splice | Splice Site (SNP) | VAF 53/296 reads (18%) | called by muse, mutect2, varscan2
- SLC2A8 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- TDRD15 | c.1387_1388insTTTA p.K463Ifs*2 | Frame Shift Ins (INS) | VAF 19/99 reads (19%) | called by mutect2, pindel, varscan2
- TTN | c.77773G>C p.D25925H (on ENST00000591111; = p.D18501H on NM_003319.4) | Missense Mutation (SNP) | VAF 29/193 reads (15%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFAT | c.2504G>T p.C835F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF431 | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 58/393 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZSWIM5 | c.2396A>C p.H799P | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRV1 | c.13416C>T p.I4472= | Silent (SNP) | VAF 32/195 reads (16%) | catalogued as COSV101315738, COSV101316319; called by muse, mutect2, varscan2
- AMPD2 | c.402G>A p.T134= | Silent (SNP) | VAF 99/675 reads (15%) | called by muse, mutect2, varscan2
- C1orf174 | c.582C>T p.P194= | Silent (SNP) | VAF 42/261 reads (16%) | catalogued as rs768641014; called by muse, mutect2, varscan2
- CDH16 | c.2163C>A p.L721= | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- COPE | c.471G>A p.L157= | Silent (SNP) | VAF 25/187 reads (13%) | called by muse, mutect2, varscan2
- IRGQ | c.400C>T p.L134= | Silent (SNP) | VAF 113/575 reads (20%) | called by muse, mutect2, varscan2
- LRP4 | c.1056G>C p.R352= | Silent (SNP) | VAF 21/680 reads (3%) | called by muse, mutect2
- NEK8 | c.90G>A p.V30= | Silent (SNP) | VAF 157/830 reads (19%) | called by muse, mutect2, varscan2
- RBBP8NL | c.39G>A p.E13= | Silent (SNP) | VAF 75/462 reads (16%) | catalogued as COSV53348919; called by muse, mutect2, varscan2
- RPGRIP1 | c.618C>T p.F206= | Silent (SNP) | VAF 48/243 reads (20%) | catalogued as rs367764758; called by muse, mutect2, varscan2
- SLFN12L | c.63C>A p.V21= (on ENST00000260908 / NM_001363830.1; = p.V39= on NM_001195790.1) | Silent (SNP) | VAF 26/223 reads (12%) | called by muse, mutect2, varscan2
- CD9 | c.448-10C>T | Intron (SNP) | VAF 30/159 reads (19%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*5108C>G | 3'UTR (SNP) | VAF 42/178 reads (24%) | called by muse, mutect2, varscan2
- DOCK1 | c.-70C>G | 5'UTR (SNP) | VAF 13/100 reads (13%) | called by muse, varscan2
- DOCK1 | c.-10C>T | 5'UTR (SNP) | VAF 12/108 reads (11%) | catalogued as rs780504348; called by muse, varscan2
- MATR3 | c.*1448A>G | 3'UTR (SNP) | VAF 8/110 reads (7%) | catalogued as rs1298787056; called by muse, mutect2
- POLG2 | c.-48G>A | 5'UTR (SNP) | VAF 104/476 reads (22%) | catalogued as rs376183896; called by muse, mutect2, varscan2
- RABEPK | c.-150C>G | 5'UTR (SNP) | VAF 66/518 reads (13%) | catalogued as rs1055235176; called by muse, mutect2, varscan2
- RPS3 | chr11:75399518 C>T | 5'Flank (SNP) | VAF 74/501 reads (15%) | catalogued as rs967151226; called by muse, mutect2, varscan2
- TMEM59L | c.664+181C>T | Intron (SNP) | VAF 20/482 reads (4%) | called by muse, mutect2
